FM case AD16251 — Foundation Medicine Adult Cancer Clinical Dataset (FM-AD)
Open-access clinical record from the NCI Genomic Data Commons (Data Release 46.0 - August 10, 2026). Disease type: Adenomas and Adenocarcinomas; Primary site: Stomach.
https://portal.gdc.cancer.gov/cases/90b910c7-958e-41f2-8161-dc13934b45c4

Female, 68.9 years: Adenocarcinoma, NOS (ICD-O-3 8140/3) of the small intestine; metastasis biopsied or resected from the pancreas. Tumor nuclei on the sequenced sample's slide: 30% (pathologist estimate recorded by GDC). Sample type: Metastatic.
